Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A25W, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A25W-01A (Primary Tumor).

[page 1 of 3]
Laboratory Services

1CD-0-3
carcinoma, hepatocellular, NOS 8170/3
Site: liver C22.0 lw 4/25/11

MRN:
PHN:
ACB:
DOB/Gender:
Telephone:
Encounter:

Surgical Pathology Report

Received Date/Time:

Specimen Description

- A. Gallbladder.
- B. Liver.
- C. Tumor thrombus - left hepatic vein.

Clinical Information

Hepatocellular carcinoma.

Diagnosis

- A. Gallbladder, cholecystectomy:
- Normal gallbladder with no pathologic abnormality.
- B. Liver, partial hepatectomy:
- Moderately differentiated hepatocellular carcinoma
- Solitary, 11.0 cm in greatest dimension, 0.8 cm from the resection margin.
- Background liver negative for cirrhosis or significant steatosis.
- C. Tumor thrombus, left hepatic vein:

On:

[page 2 of 3]
MRN:
PHN:
ACB:

Surg Pathology Report

Received Date/Time:

-Hepatocellular carcinoma with necrosis.

Reported by:

Electronically signed by
Verified:

Synoptic Report

B: Liver, Resection, Microscopic

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

PRIMARY TUMOR (pT):

pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm

REGIONAL LYMPH NODES (pN)

DISTANT METASTASIS (pM)

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 0.8 mm

Specify margin: Parenchymal resection margin

Bile duct margin cannot be assessed

*VENOUS (LARGE VESSEL) INVASION (V):

*Present

*ADDITIONAL PATHOLOGIC FINDINGS:

*None identified

Gross Description

Received are specimens A to C. All requisitions and specimen containers are labelled with the patient's name

The cassettes and AP identifiers are labelled with the Surgical Number

[page 3 of 3]
MRN:
PHN:
ACB:

Surgical Pathology Report

Received Date/Time:

A. The specimen is labelled as "gallbladder" and consists of a cholecystectomy specimen, measuring 6.0 x 2.5 x 2.5 cm. The gallbladder contains green bile and no stone. The gallbladder surface attached to the liver was sampled and submitted in A1. Representative sections of the rest of the gallbladder wall are submitted in A2.

B. The specimen is labelled as "Liver" and consists of a partial hepatectomy specimen weighing 723 grams that has been previously inked with silver nitrate. The resection margin has been painted black. The specimen measures approximately 18.0 x 13.0 x 8.0 cm. Serial sectioning through the specimen shows that 95% of the specimen is occupied by a relatively circumscribed, soft, tan mass lesion. The mass lesion measures 11.0 cm in greatest dimension. The cut surface is hemorrhagic with possible necrosis. Grossly, the mass lesion is approximately 0.8 cm to the liver resection margin.

Sections are submitted as follows:

- B1 Representative section of tumor with closest liver resection margin, which is painted black.
- B2-B6 Multiple representative sections of the mass lesion.
- B7,B8 Representative sections of the hemorrhagic and possible necrotic area.
- B9,B10 Representative sections of the uninvolved background liver parenchyma.

C. The specimen consists of one fragment of white solid mass lesion. It is submitted in toto in cassette C.

Microscopic Description

The main tumor consists of nests and cords of malignant hepatic cells with enlarged nuclei and prominent nucleoli. Globular eosinophilic inclusions are seen in many hepatocytes. There are foci of hemorrhage and necrosis present.

Source: NCI Genomic Data Commons file 8c96b129-ce1e-4a6f-ba35-22432cc56639 (TCGA-G3-A25W.F92FE7A0-15D4-45FD-BB39-E3022E30EB77.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).